Somatic mutation profile of cancer-model specimen HCM-CSHL-0160-C18-85A (3D Organoid; aliquot HCM-CSHL-0160-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0160-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 83.9 years (30,635 days).
Specimen HCM-CSHL-0160-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfc226c3-7c74-4b7f-8967-519cf899b241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0160-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0160-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/756662ed-49fc-485e-b405-1319adfc2e41

The open-access MAF lists 146 somatic variants for this specimen: 92 protein-altering or splice-affecting, 27 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 27, Intron 11, Nonsense Mutation 5, Frame Shift Del 5, RNA 5, 3'UTR 3, 5'Flank 3, 3'Flank 3, Frame Shift Ins 3, Splice Site 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.8273T>A p.L2758* | Nonsense Mutation (SNP) | VAF 29/240 reads (12%) | catalogued as rs199422178, CM095685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 259/259 reads (100%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100774887; called by muse, mutect2
- APC | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 102/189 reads (54%) | catalogued as CS971608, COSV57347627, COSV99970657; called by muse, mutect2, varscan2
- C8A | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 120/174 reads (69%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs145559867; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CCDC102A | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477882903; called by muse, mutect2, varscan2
- CHD4 | c.1582C>T p.R528W (on ENST00000357008 / NM_001363606.2; = p.R541W on NM_001273.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58899913; called by muse, mutect2, varscan2
- CNOT9 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99813791; called by muse, mutect2, varscan2
- CNTN4 | c.1979C>G p.T660S | Missense Mutation (SNP) | VAF 298/416 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100639251; called by muse, mutect2, varscan2
- COL5A3 | c.3137G>C p.G1046A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461090238, COSV99317982; called by muse, mutect2, varscan2
- CRB1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); catalogued as rs1355316419, COSV66334620; called by muse, mutect2, varscan2
- DCLK1 | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV99713821; called by muse, mutect2
- DDR2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376303676; called by muse, mutect2, varscan2
- DNAJC22 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 120/158 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs774453268; called by muse, mutect2, varscan2
- ENPP1 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 99/152 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs762065573, COSV62933486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO32 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs1280182665, COSV54890923; called by muse, mutect2, varscan2
- FOXL1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 107/147 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV100206189; called by muse, mutect2, varscan2
- GLB1L | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 94/118 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs142820300; called by muse, mutect2, varscan2
- GPT | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 497/839 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs370395815; called by muse, mutect2, varscan2
- HK3 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs372314303; called by muse, mutect2, varscan2
- IQCF5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 245/324 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1300020072; called by muse, mutect2, varscan2
- IRX5 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 133/172 reads (77%) | SIFT tolerated (0.75); PolyPhen benign (0.224); catalogued as rs1235972509, COSV58058600; called by muse, mutect2, varscan2
- KCTD15 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs762950630; called by muse, mutect2, varscan2
- LRMDA | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV65285059; called by muse, mutect2, varscan2
- MAGEB6B | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs777950806, COSV69689790; called by muse, mutect2, varscan2
- MED25 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs756463606; called by muse, mutect2, varscan2
- MROH8 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 137/512 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as rs781139699; called by muse, mutect2, varscan2
- MUC4 | c.5165C>T p.S1722F | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs779747542; called by muse, mutect2, varscan2
- NBEA | c.2931G>T p.K977N | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1344551973; called by muse, mutect2, varscan2
- PCDH17 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 119/923 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961753265; called by muse, mutect2, varscan2
- PDE1B | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 101/137 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1318082863, COSV54491363; called by muse, mutect2, varscan2
- PDZD2 | c.7216G>A p.E2406K | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs374749952; called by muse, mutect2, varscan2
- PKLR | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1350652440; called by muse, mutect2, varscan2
- PLXNA4 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100326133, COSV58111478; called by muse, mutect2, varscan2
- RBM20 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs919432113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D5 | c.791G>T p.R264L (on ENST00000444387 / NM_001103161.2; = p.R180L on NM_001103160.2) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV66706695; called by muse, mutect2, varscan2
- SIPA1 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63134853; called by muse, mutect2, varscan2
- SLC25A26 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 41/210 reads (20%) | catalogued as rs755461919; called by muse, mutect2, varscan2
- SLC26A4 | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 59/606 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs201940316; called by muse, mutect2, varscan2
- SMARCC2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57213988; called by muse, mutect2, varscan2
- ST8SIA5 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 298/298 reads (100%) | PolyPhen possibly damaging (0.738); catalogued as rs779525312, COSV100164483; called by muse, mutect2, varscan2
- SYNGAP1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 106/508 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1561781934, COSV53386049; called by muse, mutect2, varscan2
- TENM1 | c.7382G>A p.R2461Q | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs752625441; called by muse, mutect2, varscan2
- TESPA1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs375755904; called by muse, mutect2, varscan2
- THEMIS | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64072833; called by muse, mutect2, varscan2
- TRIM48 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs747964790; called by muse, mutect2, varscan2
- USP31 | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs774033372, COSV54851055; called by muse, mutect2, varscan2
- UTRN | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs143774718; called by muse, mutect2, varscan2
- VPS18 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 81/81 reads (100%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1402733811, COSV55031286; called by muse, mutect2, varscan2
- VWA7 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as rs1442938143; called by muse, mutect2, varscan2
- AMER3 | c.1932G>T p.E644D | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- APC | c.2490_2491dup p.L831Cfs*12 | Frame Shift Ins (INS) | VAF 87/128 reads (68%) | called by mutect2, pindel, varscan2
- CASKIN1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC180 | c.4142T>C p.L1381P | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCNI | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CEL | c.1993A>G p.T665A (on ENST00000673714; = p.T662A on NM_001807.6) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); called by muse, varscan2
- CHD4 | c.4891G>C p.E1631Q (on ENST00000357008 / NM_001363606.2; = p.E1642Q on NM_001273.5) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, varscan2
- CMTR2 | c.1611T>G p.F537L | Missense Mutation (SNP) | VAF 83/108 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF17 | c.989dup p.N330Kfs*14 | Frame Shift Ins (INS) | VAF 139/245 reads (57%) | called by mutect2, pindel, varscan2
- EFR3A | c.2087G>T p.R696I | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- EMSY | c.2477del p.V826Gfs*2 | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | called by mutect2, pindel, varscan2
- FANCE | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 48/622 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2
- FAT4 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GATAD2B | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSTCD | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- H3-4 | c.298_305del p.Y100Gfs*4 | Frame Shift Del (DEL) | VAF 37/273 reads (14%) | called by mutect2, pindel, varscan2
- HPS3 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF18A | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDB3 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LSM14A | c.644G>C p.R215T | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MTSS1 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 149/624 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- NAA15 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2
- OR56A3 | c.122T>A p.L41* | Nonsense Mutation (SNP) | VAF 130/247 reads (53%) | called by muse, mutect2, varscan2
- OR5M8 | c.865del p.Y289Ifs*8 | Frame Shift Del (DEL) | VAF 54/127 reads (43%) | called by mutect2, pindel, varscan2
- PDGFRL | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- PKD1 | c.12257del p.L4086Rfs*112 (on ENST00000262304 / NM_001009944.3; = p.L4085Rfs*112 on NM_000296.4) | Frame Shift Del (DEL) | VAF 247/423 reads (58%) | called by mutect2, pindel, varscan2
- PTPRM | c.861del p.P288Lfs*6 | Frame Shift Del (DEL) | VAF 62/96 reads (65%) | called by mutect2, pindel
- RAMP3 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFTN2 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 124/166 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SMC4 | c.1824dup p.S609Ifs*18 | Frame Shift Ins (INS) | VAF 26/149 reads (17%) | called by mutect2, varscan2
- SUFU | c.456_457del p.X152_splice | Splice Site (DEL) | VAF 114/388 reads (29%) | called by pindel, varscan2
- SYT1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 138/310 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLK2 | c.1787G>T p.G596V (on ENST00000326270 / NM_001284333.2; = p.G574V on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM200A | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 94/132 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM43B | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 234/326 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TRMT44 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2
- TTN | c.41551G>T p.A13851S (on ENST00000591111; = p.A6427S on NM_003319.4) | Missense Mutation (SNP) | VAF 29/209 reads (14%) | PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- USP37 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- WDR6 | c.2500C>A p.H834N | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2
- ZPLD1 | c.688G>A p.V230I (on ENST00000466937 / NM_001329788.1; = p.V246I on NM_175056.2) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ADGRA1 | c.540C>T p.Y180= | Silent (SNP) | VAF 44/63 reads (70%) | catalogued as rs780151277, COSV101192645, COSV66927407; called by muse, mutect2, varscan2
- APBB3 | c.541C>T p.L181= | Silent (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2
- APBB3 | c.540C>T p.S180= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs749729906; called by muse, mutect2
- B3GNT6 | c.801G>A p.P267= | Silent (SNP) | VAF 108/201 reads (54%) | called by muse, mutect2, varscan2
- C11orf87 | c.444G>A p.S148= | Silent (SNP) | VAF 126/254 reads (50%) | catalogued as rs779890093, COSV100535703; called by muse, mutect2, varscan2
- C1QL2 | c.123C>T p.G41= | Silent (SNP) | VAF 129/169 reads (76%) | called by muse, mutect2, varscan2
- DHX16 | c.744G>A p.A248= | Silent (SNP) | VAF 195/288 reads (68%) | catalogued as rs559637615; called by muse, mutect2, varscan2
- DOCK5 | c.258C>T p.P86= | Silent (SNP) | VAF 9/227 reads (4%) | catalogued as rs1563335371; called by muse, mutect2
- EIPR1 | c.870G>A p.T290= | Silent (SNP) | VAF 43/271 reads (16%) | catalogued as rs761019969, COSV66132065, COSV66133651; called by muse, mutect2, varscan2
- EPHA3 | c.1200G>A p.L400= | Silent (SNP) | VAF 197/282 reads (70%) | called by muse, mutect2, varscan2
- ETV6 | c.1086C>T p.D362= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- FANCB | c.2394C>T p.V798= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs190579053, COSV100146578; ClinVar: benign; called by muse, mutect2, varscan2
- FLT4 | c.2127C>T p.I709= | Silent (SNP) | VAF 122/235 reads (52%) | catalogued as COSV56097933; called by muse, mutect2, varscan2
- H1-1 | c.408T>C p.S136= | Silent (SNP) | VAF 84/381 reads (22%) | catalogued as rs771426908; called by muse, mutect2, varscan2
- LCORL | c.357T>C p.S119= | Silent (SNP) | VAF 79/197 reads (40%) | called by muse, mutect2, varscan2
- LSS | c.1485T>C p.N495= | Silent (SNP) | VAF 137/310 reads (44%) | catalogued as rs985166790; called by muse, mutect2, varscan2
- MMP2 | c.681C>T p.N227= | Silent (SNP) | VAF 325/431 reads (75%) | catalogued as rs558609366, COSV54604672; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4D10 | c.834C>A p.I278= | Silent (SNP) | VAF 64/134 reads (48%) | called by muse, varscan2
- PGP | c.183G>A p.K61= | Silent (SNP) | VAF 77/322 reads (24%) | catalogued as rs1263222794; called by muse, mutect2, varscan2
- PKLR | c.831G>A p.E277= | Silent (SNP) | VAF 118/417 reads (28%) | called by muse, mutect2, varscan2
- SRD5A2 | c.264C>T p.C88= | Silent (SNP) | VAF 70/82 reads (85%) | catalogued as rs867198056, COSV99252314; called by muse, varscan2
- TBCD | c.1554G>C p.V518= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1032C>T p.S344= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- TRIM51 | c.177G>A p.T59= | Silent (SNP) | VAF 105/228 reads (46%) | catalogued as rs747498461, COSV55268028; called by muse, mutect2, varscan2
- USP28 | c.2946G>A p.L982= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- USP29 | c.2496C>A p.I832= | Silent (SNP) | VAF 92/189 reads (49%) | catalogued as COSV54145949; called by muse, mutect2, varscan2
- WIZ | c.1041G>A p.A347= | Silent (SNP) | VAF 75/152 reads (49%) | catalogued as rs927604183; called by muse, mutect2, varscan2
- AC245047.1 | n.107C>T | RNA (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196357 G>A | 3'Flank (SNP) | VAF 311/593 reads (52%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100105888 C>T | 5'Flank (SNP) | VAF 359/486 reads (74%) | catalogued as rs1200636499; called by muse, mutect2, varscan2
- AL110118.1 | c.207+2478G>A | Intron (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840559 G>T | 5'Flank (SNP) | VAF 71/214 reads (33%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849031 A>G | 5'Flank (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.479A>C | RNA (SNP) | VAF 102/196 reads (52%) | called by muse, mutect2, varscan2
- APOOP5 | n.391C>A | RNA (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ASL | c.602+38G>A | Intron (SNP) | VAF 82/178 reads (46%) | called by mutect2, varscan2
- ATP6AP2 | c.-7C>T | 5'UTR (SNP) | VAF 146/475 reads (31%) | called by muse, mutect2, varscan2
- CAMK2G | c.1273+725C>T | Intron (SNP) | VAF 85/154 reads (55%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1479G>C | Intron (SNP) | VAF 78/78 reads (100%) | catalogued as rs971864132; called by muse, mutect2
- FAF2 | c.-18C>G | 5'UTR (SNP) | VAF 73/392 reads (19%) | called by muse, mutect2, varscan2
- FKBP11 | c.388+207G>A | Intron (SNP) | VAF 138/210 reads (66%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-968A>T | Intron (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- IDS | c.419-1082C>T | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs782598072; called by muse, mutect2, varscan2
- ITPR1 | c.855+46G>T | Intron (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101893239 G>T | 3'Flank (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85441C>T | Intron (SNP) | VAF 143/310 reads (46%) | catalogued as rs537870223, COSV72275109; called by muse, varscan2
- MUC19 | n.5591G>T | RNA (SNP) | VAF 23/31 reads (74%) | called by muse, mutect2, varscan2
- NPIPP1 | n.262C>T | RNA (SNP) | VAF 168/362 reads (46%) | called by muse, mutect2, varscan2
- PPAT | c.403-659A>C | Intron (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- SDHA | c.1794+98C>T | Intron (SNP) | VAF 158/300 reads (53%) | called by muse, varscan2
- SYT14 | c.*1169T>C | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- TMEM14B | chr6:10759085 ins T | 3'Flank (INS) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- ULK1 | c.*632C>A | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- ZNF747 | c.*520G>T | 3'UTR (SNP) | VAF 66/353 reads (19%) | catalogued as rs1239556758; called by muse, mutect2, varscan2
